Somatic mutation profile of tumor specimen 0D8CGJ from CCDI case PBBHGD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.1 years (4,800 days).
Specimen 0D8CGJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6bce63f2-6355-46bc-b1f2-ac61d2b00ca3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D8CGO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ed36676-f298-438b-9782-dd55968d9509

The open-access MAF lists 58 somatic variants for this specimen: 38 protein-altering or splice-affecting, 11 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 11, Splice Region 3, 3'UTR 3, Intron 3, 5'UTR 2, Nonsense Mutation 2, Frame Shift Del 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABLIM3 | c.888C>T p.C296= | Splice Region (SNP) | VAF 166/572 reads (29%) | catalogued as rs750368924, COSV58650828; called by muse, mutect2, varscan2
- ARHGEF2 | c.1117G>A p.A373T (on ENST00000361247 / NM_001162383.2; = p.A345T on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 117/625 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as rs778354915; called by muse, varscan2
- CCDC190 | c.177G>T p.R59S | Missense Mutation (SNP) | VAF 264/606 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as COSV63362964; called by muse, mutect2, varscan2
- CCDC22 | c.673G>C p.D225H | Missense Mutation (SNP) | VAF 149/747 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV66109167; called by muse, mutect2, varscan2
- CCDC88B | c.4377C>A p.G1459= | Splice Region (SNP) | VAF 192/438 reads (44%) | catalogued as COSV53702887; called by muse, mutect2
- GTF3C1 | c.2401C>T p.R801W | Missense Mutation (SNP) | VAF 297/625 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs1205133504, COSV62244312; called by muse, mutect2, varscan2
- HSPG2 | c.8254G>A p.G2752R | Missense Mutation (SNP) | VAF 242/550 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs143734280; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MTSS1 | c.1283G>A p.R428H | Missense Mutation (SNP) | VAF 269/860 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1252270636, COSV61496871; called by muse, mutect2, varscan2
- NAB2 | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 139/768 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1281525385; called by muse, mutect2, varscan2
- OR4N2 | c.382C>T p.R128W | Missense Mutation (SNP) | VAF 436/3289 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs746490349, COSV60050917; called by muse, mutect2, varscan2
- POLR1B | c.445C>G p.R149G | Missense Mutation (SNP) | VAF 159/1203 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as COSV54499151, COSV54500977; called by muse, mutect2, varscan2
- SLC22A8 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 45/588 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs45566039, COSV100267647; called by muse, mutect2
- SNAPC4 | c.4066C>T p.Q1356* | Nonsense Mutation (SNP) | VAF 18/278 reads (6%) | catalogued as rs1039670637; called by muse, mutect2
- WNK3 | c.3727C>T p.H1243Y | Missense Mutation (SNP) | VAF 272/1228 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV63612003, COSV63612579; called by muse, mutect2, varscan2
- ACE | c.1196T>C p.L399P | Missense Mutation (SNP) | VAF 257/1148 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADAMTS16 | c.1234A>T p.S412C | Missense Mutation (SNP) | VAF 81/1043 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ANKRD30B | c.1825+1G>T p.X609_splice | Splice Site (SNP) | VAF 122/613 reads (20%) | called by muse, mutect2, varscan2
- ATP6V1C2 | c.88A>C p.N30H | Missense Mutation (SNP) | VAF 671/1069 reads (63%) | SIFT deleterious (0.05); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- BCORL1 | c.3028C>G p.P1010A | Missense Mutation (SNP) | VAF 36/1427 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.925); called by muse, mutect2
- BEST1 | c.54_55del p.R19Pfs*32 | Frame Shift Del (DEL) | VAF 70/584 reads (12%) | called by mutect2, varscan2
- CEP126 | c.3085T>G p.S1029A | Missense Mutation (SNP) | VAF 341/766 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- CLCN5 | c.1402C>T p.L468F | Missense Mutation (SNP) | VAF 350/1131 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- F9 | c.24G>T p.M8I | Missense Mutation (SNP) | VAF 256/1274 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, varscan2
- FMNL3 | c.114C>G p.F38L | Missense Mutation (SNP) | VAF 109/524 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- FOXD1 | c.1006G>T p.A336S | Missense Mutation (SNP) | VAF 76/171 reads (44%) | SIFT tolerated (0.56); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- FYCO1 | c.2095G>T p.E699* | Nonsense Mutation (SNP) | VAF 167/632 reads (26%) | called by muse, mutect2, varscan2
- HTATSF1 | c.1103G>T p.G368V | Missense Mutation (SNP) | VAF 251/974 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- HUS1 | c.392A>T p.H131L | Missense Mutation (SNP) | VAF 259/877 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- ITGB3 | c.1889G>T p.C630F | Missense Mutation (SNP) | VAF 419/1398 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRK1 | c.1261G>C p.D421H | Missense Mutation (SNP) | VAF 188/701 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- MR1 | c.328+8T>C | Splice Region (SNP) | VAF 28/230 reads (12%) | called by muse, mutect2, varscan2
- OLFML2B | c.131C>T p.T44I | Missense Mutation (SNP) | VAF 271/871 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- POLA1 | c.2153C>G p.T718S | Missense Mutation (SNP) | VAF 117/747 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- PTP4A2 | c.367T>G p.Y123D | Missense Mutation (SNP) | VAF 204/675 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- SOX3 | c.598A>G p.M200V | Missense Mutation (SNP) | VAF 295/1032 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- ZC3H12B | c.2249G>T p.S750I | Missense Mutation (SNP) | VAF 86/1788 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.091); called by muse, mutect2
- ZNF541 | c.2263T>C p.S755P | Missense Mutation (SNP) | VAF 16/317 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.013); called by muse, mutect2
- ZNF571 | c.1796C>T p.S599L | Missense Mutation (SNP) | VAF 141/340 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- F8 | c.2151G>T p.R717= | Silent (SNP) | VAF 74/1399 reads (5%) | called by muse, mutect2
- GPAT2 | c.1302C>A p.A434= | Silent (SNP) | VAF 59/773 reads (8%) | called by muse, mutect2, varscan2
- NAALADL1 | c.1500G>T p.L500= | Silent (SNP) | VAF 102/560 reads (18%) | called by muse, mutect2, varscan2
- PCED1B | c.1230G>A p.T410= | Silent (SNP) | VAF 196/852 reads (23%) | catalogued as rs775815786; called by muse, mutect2, varscan2
- PLEKHH2 | c.4167A>T p.I1389= | Silent (SNP) | VAF 204/1028 reads (20%) | called by muse, mutect2, varscan2
- SCN3A | c.3714C>A p.T1238= | Silent (SNP) | VAF 70/851 reads (8%) | catalogued as COSV51819092; called by muse, mutect2
- SERPINE1 | c.378G>T p.L126= | Silent (SNP) | VAF 50/1000 reads (5%) | called by muse, mutect2
- SLC16A7 | c.906A>G p.L302= | Silent (SNP) | VAF 202/877 reads (23%) | called by muse, mutect2, varscan2
- TMPRSS11B | c.597G>A p.Q199= | Silent (SNP) | VAF 39/745 reads (5%) | catalogued as COSV100219327; called by muse, mutect2
- TTC3 | c.3486T>C p.F1162= | Silent (SNP) | VAF 406/940 reads (43%) | called by muse, mutect2, varscan2
- ZNF716 | c.27A>G p.G9= | Silent (SNP) | VAF 252/1511 reads (17%) | called by muse, mutect2, varscan2
- COL4A5 | c.384+25G>T | Intron (SNP) | VAF 178/574 reads (31%) | called by muse, mutect2, varscan2
- CSTF2 | chrX:100820359 G>C | 5'Flank (SNP) | VAF 23/252 reads (9%) | called by muse, mutect2
- FBLN7 | c.*8C>T | 3'UTR (SNP) | VAF 80/525 reads (15%) | called by muse, mutect2, varscan2
- GADL1 | c.-43T>A | 5'UTR (SNP) | VAF 55/108 reads (51%) | called by muse, mutect2, varscan2
- HOXB1 | c.577+31G>A | Intron (SNP) | VAF 65/341 reads (19%) | catalogued as rs996157823; called by muse, mutect2, varscan2
- NUP50 | c.*13G>A | 3'UTR (SNP) | VAF 167/363 reads (46%) | catalogued as rs761314487; called by muse, mutect2, varscan2
- SLC37A2 | c.*29G>A | 3'UTR (SNP) | VAF 62/753 reads (8%) | called by muse, mutect2
- TNFRSF10C | c.167-98T>A | Intron (SNP) | VAF 21/46 reads (46%) | called by muse, varscan2
- TRPA1 | c.-69C>G | 5'UTR (SNP) | VAF 13/45 reads (29%) | called by muse, mutect2, varscan2
